Surgical pathology report (de-identified scan), TCGA case TCGA-5G-A9ZZ, project TCGA-THYM (Thymoma), tissue source site Cleveland Clinic Foundation, specimen TCGA-5G-A9ZZ-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Specimen #: [REDACTED]

Patient ID #: [REDACTED]

DOB: [REDACTED]

Client: [REDACTED]

Physician(s): [REDACTED]

Date of Procedure:

Date of Receipt:

Date of Report:

Location:

SPECIMEN SUBMITTED

A: THYMOMA

B: SUPERIOR MEDIASTINAL LYMPH NODE

C: LEFT SIDED THYMUS

ICD O-3
Thymoma, type C 8586/3
Site: Thymus C379
JW 4/22/14

FINAL DIAGNOSIS

1. Thymoma, excision (A) – Thymic epithelial neoplasm with features of thymic carcinoma and thymoma (see comment).
2. Superior mediastinal lymph node, excision (B) - Lymph node; negative for neoplasm.
3. Left sided thymus, excision (C) - Thymic tissue with no significant pathologic changes.

COMMENT

1. The tumor is composed of a predominantly epithelial thymic proliferation consisting of nests and sheets of polygonal cells with round nuclei with vesicular chromatin and prominent nucleoli, separated by prominent lymphoid stroma. The cells show marked nuclear atypia in some areas as well as numerous mitotic figures. The tumor is arranged in lobules separated by fibrous trabeculae; however there are patchy foci of dense hyalinizing fibrosis separating small irregular nests. Prominent lymphoplasmacytic infiltrates and lymphovascular invasion are also present. These features are in favor of thymic carcinoma. The tumor invades through the capsule. The tumor measures 5.5 x 3.5 x 2.2 cm. The tumor approaches the surgical margin in some foci, but it is surrounded entirely by a thin layer of fibrous tissue (less than 0.1 cm).

Selected slides from this case have been sent to
diagnosis reads as follows:

His

"Thymic epithelial neoplasm, favor thymic carcinoma, 5.5 cm in greatest dimension. Tumor focally invades into the capsule".

"Immunohistochemical stain performed and the results show the tumor cells are strongly positive for CD5. Ki-67 stain highlights approximately 20% of the cells."

Electronic Signature

CLINICAL DATA

[REDACTED]

[page 2 of 2]
THYMOMA

GROSS DESCRIPTION

A. Received fresh for frozen diagnosis labeled "thymoma" is a right thymus weighing 60.1 grams and measuring 9.5 x 4.5 x 3.5 cm. The resection surface is inked black. The specimen is serially sectioned to reveal a tan mass with cystic areas that has yellow fluid in it. The mass measures 5.5 x 3.5 x 2.2 cm. No areas of necrosis are identified. No areas of hemorrhage are identified. The mass appears to be grossly well circumscribed. The specimen is submitted as follows: FSA1 frozen diagnosis; A2 closest margins with ink; A3 closest margin with ink; A4 closest margin with ink; A5-A7 closest margins, no ink; A8-A25 remainder of the specimen submitted superior to inferior.

B. Received fresh is a tan-pink nodule resembling a lymph node measuring 0.5 x 0.5 x 0.3 cm. Totally submitted in one cassette.

C. Received in formalin is a tan-yellow segment of fibroadipose tissue labeled "left sided thymus" measuring 5.5 x 3.7 x 1.1 cm, and weighing 12.9 grams. The external surface is inked in black. The specimen is sectioned to reveal a tan-yellow lobulated cut surface. Representative sections are submitted in three cassettes.

INTRAOPERATIVE CONSULT DIAGNOSIS

A. Thymoma. Margins are negative (gross examination with representative microscopic sections)

Source: NCI Genomic Data Commons file 820287d7-0edd-444f-ac63-6194b23bb7ad (TCGA-5G-A9ZZ.C98B0A4E-E03E-428B-A2C1-CFDFB0D70F56.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).